Gene-level copy-number profile of tumor specimen TCGA-AR-A1AS-01A from TCGA case TCGA-AR-A1AS, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 54.8 years (20,028 days).
Specimen TCGA-AR-A1AS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.8fcff679-66ba-4348-93ed-eb7166302c3e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AR-A1AS-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a9a13d3f-a24e-439f-a458-fdcf59363053

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,746; copy number 2: 50,307; copy number 3: 3,746; copy number 4: 205; copy number 5: 2,611; copy number 6: 1,204.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AR-A1AS-01A-11D-A12N-01): tumor purity 0.77, ploidy 2.16, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,815 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 5 (broad region; genes not listed).
- chr3:99,215,224–99,529,985, 4 genes, copy number 6: ACTG1P13, AC107297.1, AC078828.1, AC107029.1.
- chr16:11,555–31,603,531, 1,200 genes, copy number 6 (broad region; genes not listed).
- chr16:67,943,474–68,000,586, 3 genes, copy number 5: SLC12A4, DPEP3, DPEP2.
- chr16:68,002,432–68,023,232, 4 genes, copy number 5: KARS1P3, DPEP2NB, RNU6-359P, DDX28.

Autosomal genes at a single copy (total copy number 1): 1,746. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
